Gene-level copy-number profile of tumor specimen TCGA-CR-7398-01A from TCGA case TCGA-CR-7398, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 53.3 years (19,468 days).
Specimen TCGA-CR-7398-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.52528ac8-e86d-4a55-b4e8-5f937c7f43b6.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CR-7398-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 398 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2bd56714-1fb8-47df-b1b2-15275d905ac1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 522; copy number 1: 16,208; copy number 2: 33,437; copy number 3: 3,113; copy number 4: 4,543; copy number 5: 962; copy number 6: 830; copy number 7: 33; copy number 8: 414; copy number 9: 163.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CR-7398-01A-11D-2010-01): tumor purity 0.79, ploidy 1.94, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:97,737,894–97,738,913, 1 gene: AC112203.1.
- chr12:48,559,882–48,562,956, 1 gene: OR5BS1P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,402 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–45,895,970, 710 genes, copy number 5–7 (broad region; genes not listed).
- chr12:66,767–30,217,916, 748 genes, copy number 5–9 (broad region; genes not listed).
- chr12:30,628,988–34,249,958, 97 genes, copy number 5–9 (broad region; genes not listed).
- chr12:72,610,678–73,208,317, 5 genes, copy number 5–6: CHCHD3P2, AC133480.1, AC090503.2, LINC02444, AC090503.1.
- chr18:20,946,906–39,034,110, 271 genes, copy number 5 (broad region; genes not listed).
- chr18:39,314,240–39,335,672, 2 genes, copy number 5: AC011139.1, RPL7AP66.
- chr18:42,159,283–80,247,514, 569 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 15,145. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
